Gene-level copy-number profile of tumor specimen ALCH-ADTB-TTP1-A from ALCHEMIST case ALCH-ADTB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell neuroendocrine carcinoma; Age at diagnosis: 77.5 years (28,316 days).
Specimen ALCH-ADTB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 76b2cf3d-7761-4f47-8d62-ba2a040f2c8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADTB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/42add300-ce70-42c1-94fa-85b5a0332575

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 16,009; copy number 2: 39,389; copy number 3: 2,596; copy number 4: 423; copy number 5: 278; copy number 6: 66; copy number 7: 7; copy number 8: 10; copy number 9: 2; copy number 10: 22; copy number 14: 15; copy number 16: 44; copy number 18: 6; copy number 19: 8; copy number 26: 13.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:73,461,578–73,525,587, 4 genes (within-gene range 0–1): MTO1, RNU6-975P, RN7SL827P, EEF1A1.
- chr7:68,723,911–68,724,048, 1 gene: RNA5SP231.
- chr14:63,762,013–63,808,732, 2 genes: AL161670.1, RPS28P1.
- chr14:91,091,077–91,091,138, 1 gene (within-gene range 0–1): RNU7-30P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 471 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,050,441–149,917,844, 135 genes, copy number 5 (broad region; genes not listed).
- chr1:166,474,879–167,591,846, 28 genes, copy number 5 (within-gene range 2–5): LINC01675, FMO8P, FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1.
- chr1:188,508,538–192,957,713, 34 genes, copy number 5–6 (within-gene range 4–6): AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1.
- chr1:202,724,495–204,041,265, 49 genes, copy number 6: KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A, PPFIA4, MYOG, ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1, CHIT1, NPM1P40, LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303.
- chr1:207,104,233–209,432,838, 40 genes, copy number 5–19: C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, PLXNA2, AL590138.1, AL606753.1, LINC01735, LINC02769, RPS26P13, LINC01717, LINC01774, AC104465.1, AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205.
- chr1:210,328,252–210,676,296, 2 genes, copy number 8 (within-gene range 4–8): HHAT, AL034351.4.
- chr1:210,386,657–211,207,138, 8 genes, copy number 8 (within-gene range 2–8): AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3.
- chr1:245,749,342–246,507,312, 1 gene, copy number 5 (within-gene range 2–5): SMYD3.
- chr1:246,108,626–248,101,103, 88 genes, copy number 5–16 (within-gene range 2–16) (broad region; genes not listed).
- chr5:710,355–1,345,099, 21 genes, copy number 9–26: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:10,057,502–13,638,381, 52 genes, copy number 5–16: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1.
- chr5:14,143,342–14,871,778, 11 genes, copy number 5 (within-gene range 4–5): TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1.
- chr5:28,213,359–28,287,807, 2 genes, copy number 5: AC093300.1, LINC02103.

Autosomal genes at a single copy (total copy number 1): 13,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
